Surgical pathology report (de-identified scan), TCGA case TCGA-PC-A5DN, project TCGA-SARC (Sarcoma), tissue source site Fox Chase, specimen TCGA-PC-A5DN-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN:
SURGICAL PATHOLOGY REPORT

DOB:
Sex: F
Location:
Date Collected:
Date Received:
Physician:
Copy To:
Clinical History/Diagnosis: Left Retroperitoneal Mass

ICD-O-3
Xenograftoma NOS
8890/3
Site: Retroperitoneum
C48.0
JW 5/24/13

Source of Specimen(s):
1: Retroperitoneal mass with lt. kidney
2: Lymph Node, intra aortocaval
3: Lymph Node, para aortic

Gross Description:
Received in three parts.
Source of Tissue: 1. Labeled #1, "retroperitoneal mass with left kidney"

Frozen Section Diagnosis: 1FS- SPINDLE CELL NEOPLASM PER

Gross Description: Received fresh for frozen section evaluation with patient name and medical record number labeled "retroperitoneal mass with left kidney" is a 26.0 x 20.0 x 12.5 cm mass having a tan to pink-red smooth to irregular outer surface. It is sectioned to reveal a 20.0 cm in greatest dimension multiloculated cyst containing serosanguineous fluid. The inner lining is gray-tan and irregular with the cyst wall averaging 1.5 cm in thickness. The wall is tan and rubbery firm. Firmly adherent to this cystic mass is a 9.0 x 5.5 x 4.5 cm kidney. There is a 1.5 x 0.3 cm fragment of attached ureter having a lumen, 0.2 cm which is probe patent to the renal hilum. The kidney is bivalved to reveal tan-brown renal parenchyma having a well-defined cortico-medullary junction. The parenchyma and pelvis are not distorted and the adjacent tumor does not appear to arise from the kidney itself. Further sectioning of the cystic mass in the area of the kidney reveals areas which are focally calcified. There is a 5.0 x 1.5 x 1.0 cm attached adrenal gland which is sectioned to reveal golden-yellow-orange unremarkable cut surfaces. Representative sections are submitted in eighteen blocks.

Designation of Sections: 1FS- frozen section cystic mass, 1A- ureter and vascular margins, kidney, 1B-1C- random kidney with adjacent mass, 1D- adrenal gland, 1E-1R- representative sections cystic mass

Summary of Sections: multiple

Print Malignancy History		

[page 2 of 2]
Source of Tissue: 2. Labeled #2, "intra aortocaval lymph node"

Gross Description: Received fresh with patient name and medical record number labeled "intra aortocaval lymph node" are 2.0 x 1.0 x 0.8 cm of yellow-tan fibroadipose tissue. There are two palpable lymph nodes, 1.8 cm in greatest dimension. The lymph nodes are entirely submitted in three blocks.

Designation of Sections: 2A-2B- one lymph node, 2C- one lymph node

Summary of Sections: multiple

Source of Tissue: 3. Labeled #3, "para aortic lymph node"

Gross Description: Received fresh with patient name and medical record number labeled "para aortic lymph node" is a 1.5 cm in greatest dimension red-purple soft lymph node which is entirely submitted in one block.

Designation of Sections: Block 3

Summary of Sections: undesignated-2

Final Diagnosis:

1. Retroperitoneal mass with left kidney, resection:
- High-grade spindle cell sarcoma consistent with CD117 positive leiomyosarcoma (20.0 cm), see comment.
- The tumor surrounds, but not invades into, left kidney, ureter and adrenal.
- Kidney with chronic pyelonephritis. Adrenal gland with no pathological changes.

Comment: The morphology at the tumor suggests leiomyosarcoma. Tumor cells stain strongly positive for SMA, weakly positive for CD-117. They are negative for Desmin and CD34. The case is reviewed by _____ and he concurs with the diagnosis.

2. Intra aortocaval lymph nodes, biopsy:
- Two lymph nodes, no tumor seen (0/2).
3. Para aortic lymph nodes, biopsy:
- One lymph node, no tumor seen (0/1).

Source: NCI Genomic Data Commons file 3e46630b-dacc-4755-a9ba-0da753c3946b (TCGA-PC-A5DN.9CCFF5D2-9AE9-429C-9386-7259364AC7DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).